Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A3DJ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A3DJ-01A (Primary Tumor).

Case #: DOB Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Melanoma** Histological description: **Melanoma**

Date of Procurement: Anatomic Site: **Skin** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Surgery** Grade: **3**

T Stage: **4b** N Stage: **1** M Stage: **0** Treatment: **no**

Treatment Details: **no/no**

*ICD-O-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9*

Normal Sample

Anatomic Site: **Blood** Sample Type: **normal** Type of Procurement: **Blood draw**

Matrix: **Blood** Specimen Format: **Frozen** Container: **tube**

Date of Procurement:

*lw
10/15/11*

Source: NCI Genomic Data Commons file e4cfa454-171c-488e-bb46-124fa565bc35 (TCGA-BF-A3DJ.BF41787D-E227-4BD0-A090-A6A44B5763E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).